Somatic mutation profile of tumor specimen TARGET-30-PAUKNU-01A (aliquot TARGET-30-PAUKNU-01A-01D) from TARGET case TARGET-30-PAUKNU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.0 years (729 days).
Specimen TARGET-30-PAUKNU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7d69faa-834f-4d49-b8ca-a8440dc97e81.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUKNU-10A (Blood Derived Normal), aliquot TARGET-30-PAUKNU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2fdbbe1-31f1-4b35-8159-e17670ee8fb4

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF40 | c.1185G>A p.G395= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV100070798; called by muse, mutect2
- NOS1 | c.*4504G>T | 3'UTR (SNP) | VAF 25/166 reads (15%) | called by muse, mutect2, varscan2
